Somatic mutation profile of tumor specimen 0DI3LZ from CCDI case PBBVCD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,671 days).
Specimen 0DI3LZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59a3665-aaf1-425e-bee9-f5d11db8933b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/354d383b-991f-4183-9ec6-91c15433a4e0

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAF15 | c.1604G>A p.R535H (on ENST00000605844 / NM_139215.3; = p.R532H on NM_003487.4) | Missense Mutation (SNP) | VAF 114/844 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs532683371; called by muse, mutect2, varscan2
- ALDH1A3 | c.1084T>C p.F362L | Missense Mutation (SNP) | VAF 120/973 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA0586 | c.3925C>A p.Q1309K (on ENST00000619416 / NM_001244190.2; = p.Q1248K on NM_014749.5) | Missense Mutation (SNP) | VAF 167/1211 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MARF1 | c.2264C>A p.S755Y | Missense Mutation (SNP) | VAF 68/612 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- SCN10A | c.5380C>T p.P1794S | Missense Mutation (SNP) | VAF 158/1122 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VPS11 | c.-62A>T | Splice Region (SNP) | VAF 42/750 reads (6%) | called by muse, mutect2
- WDR97 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
